Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5853, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5853-01A (Primary Tumor).

[page 1 of 4]
=====

CLINICAL HISTORY

Brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, left frontal tumor, biopsy

B: Left frontal brain tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, left frontal tumor, excision biopsy:
Oligoastrocytoma (WHO

Grade II) (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis of low-grade glioma.

The tumor cells have round to oval to angulated nuclei in a background of

delicate vessels and ropy myelin. Mitotic figures are rare and vascular

proliferation is not seen.

The tumor is diffusely p53 positive. The Ki-67 labeling index is approximately

4 to 5%.

Positive and negative controls show appropriate immunoreactivity.

Analysis of chromosome segments 1p and 19q and MGMT promoter methylation will

be reported below in procedure addenda.

=====

[page 2 of 4]
NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S1592, D19S219, PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block.

DNA extracted from a corresponding blood specimen was used as normal reference control.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

[page 3 of 4]
Testing performed on DNA extracted from tumor paraffin block.
TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Left frontal brain tumor, excision biopsy: Atypical glial proliferation consistent with a low-grade glioma. Frozen section and smears performed at [REDACTED]

GROSS DESCRIPTION

A. Brain, left frontal tumor, biopsy:
Received fresh and labelled with the patient's name and medical record number, are two biopsy fragments for intraoperative evaluation. The fragments aggregate 0.5 x 0.5 x 0.3 cm, are tan-pink, and are soft. Entirely submitted

[page 4 of 4]
in two cassettes as: A1 frozen section remnants and A2 remainder of the specimen.

B. Left frontal brain tumor, excision biopsy:

CONTAINER LABEL: Left frontal brain tumor

FIXATIVE: Formalin. NO. PIECES: multiple tan-pink, soft tissue fragments.

SIZE/VOL: 2.8 x 1.8 x 0.5 cm, in aggregate. CASSETTES: 2, NS. Mid, 19:12.

ICD-9(s):

Billing Fee Code(s):

Histo Data

Part A: Brain, left frontal tumor, biopsy

Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1		
H/E x 1	1		
Rct 1 H/E x 1	1		
TPS Triage x 1	1		
H/E x 1	2		
Rct 1 H/E x 1	2		

Part B: Left frontal brain tumor, biopsy

Stain/cnt	Block	Comment
H/E x 1	1	
LOH-curles x 1	1	
MGMT-curles x 1	1	
MIB1-DA x 1	1	
P53DO7 x 1	1	
Rct 1 H/E x 1	1	
H/E x 1	2	
MIB1-DA x 1	2	
P53DO7 x 1	2	
Rct 1 H/E x 1	2	

*** End of Report ***

Source: NCI Genomic Data Commons file d478a9c7-1491-49bf-8dd5-d8ceebf0e105 (TCGA-DU-5853.D4BDA6A8-21EF-4395-9091-DCD87E011D9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).